FM case AD4931 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms; Primary site: Other and ill-defined sites.
https://portal.gdc.cancer.gov/cases/817794ea-49d9-499c-bd97-cbed40d60b06

Male, 58.6 years: Squamous cell carcinoma, NOS (ICD-O-3 8070/3) of the head, face or neck; specimen biopsied or resected from the lung. Tumor nuclei on the sequenced sample's slide: 50% (pathologist estimate recorded by GDC). Sample type: Tumor.
